Gene-level copy-number profile of tumor specimen TCGA-LN-A4A8-01A from TCGA case TCGA-LN-A4A8, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 52.1 years (19,046 days).
Specimen TCGA-LN-A4A8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.6738f5b4-5e4a-4d2c-b78e-13c4d8d5e1cf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A4A8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/58ee75bc-5305-4e6e-9779-d332265f1ff6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 10,778; copy number 2: 39,892; copy number 3: 7,880; copy number 4: 302; copy number 6: 648; copy number 7: 86; copy number 11: 83; copy number 14: 48; copy number 16: 54; copy number 22: 14; copy number 31: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A4A8-01A-32D-A25X-01): tumor purity 0.71, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–1): MTAP, AL359922.1.
- chr9:21,858,910–21,995,301, 5 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 949 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,752,250–55,646,951, 16 genes, copy number 31: SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6.
- chr11:66,848,417–70,436,584, 138 genes, copy number 6–14 (within-gene range 2–14) (broad region; genes not listed).
- chr11:70,477,277–70,647,562, 4 genes, copy number 14: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2.
- chr12:66,767–24,562,544, 636 genes, copy number 6–22 (within-gene range 3–22) (broad region; genes not listed).
- chr12:26,335,352–26,833,194, 1 gene, copy number 6 (within-gene range 3–6): ITPR2.
- chr12:26,623,369–30,492,302, 68 genes, copy number 6 (broad region; genes not listed).
- chr20:62,938,147–64,313,132, 86 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,490. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
